Gene-level copy-number profile of tumor specimen C3N-01023-04 from CPTAC case C3N-01023, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 58.2 years (21,265 days).
Specimen C3N-01023-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b36a4db8-6f0e-4d70-ac1f-7c202d50f23d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-01023-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,854 have no estimate.
https://portal.gdc.cancer.gov/files/6373acc0-0c68-48db-99c1-daa5b8dcab32

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 299; copy number 1: 16,261; copy number 2: 33,629; copy number 3: 8,299; copy number 4: 172; copy number 5: 59; copy number 6: 15; copy number 10: 35.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:73,522,878–73,530,610, 1 gene (within-gene range 0–2): AC005225.3.
- chr16:32,475,051–32,478,250, 1 gene: ABCD1P3.
- chr18:2,948,238–2,960,756, 1 gene (within-gene range 0–2): AP000919.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 109 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:31,025,106–36,656,163, 109 genes, copy number 5–10 (within-gene range 3–10) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 13,847. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
